Somatic mutation profile of tumor specimen 0DCMP6 from CCDI case PBBMMW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 6.3 years (2,309 days).
Specimen 0DCMP6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e1703f5-9a72-4884-9458-80e5022d8bb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCMP5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4a241c6-b220-48a0-a1ef-0b647f69cecb

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 40/1382 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- GRIA3 | c.234G>T p.L78F | Missense Mutation (SNP) | VAF 450/515 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC16 | c.40320C>T p.F13440= | Silent (SNP) | VAF 98/1192 reads (8%) | catalogued as COSV66690504; called by muse, mutect2
- DPEP2NB | c.*96A>G | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by mutect2, varscan2
